Somatic mutation profile of tumor specimen TCGA-HT-7473-01A (aliquot TCGA-HT-7473-01A-11D-2024-08) from TCGA case TCGA-HT-7473, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 28.2 years (10,306 days).
Specimen TCGA-HT-7473-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e3a16bd-a03e-44e6-bb97-f3c335a71585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7473-10A (Blood Derived Normal), aliquot TCGA-HT-7473-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10bd25f7-6193-4b79-9902-70681aca386b

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 17/22 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMBT1 | c.6283C>T p.R2095W (on ENST00000338354 / NM_001377530.1; = p.R1338W on NM_004406.3) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs369082605; called by muse, mutect2, varscan2
- EXPH5 | c.4763G>T p.R1588I | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56201858; called by muse, mutect2, varscan2
- LRRC43 | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV60289788; called by muse, mutect2, varscan2
- NLRP6 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.649); catalogued as COSV56459552; called by muse, mutect2, varscan2
- RYR2 | c.3704G>T p.G1235V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63683523; called by muse, mutect2, varscan2
- SPATA31D1 | c.3308A>G p.K1103R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV61195354; called by muse, mutect2, varscan2
- SSB | c.579T>A p.N193K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.164); catalogued as COSV53626449; called by muse, mutect2, varscan2
- ATRX | c.2295_2296insA p.D766Rfs*10 | Frame Shift Ins (INS) | VAF 72/134 reads (54%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBC1D3F | c.1461C>A p.D487E | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CALCR | c.828G>C p.R276= (on ENST00000649521 / NM_001164737.2; = p.R260= on NM_001742.4) | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV64007395, COSV64007832; called by muse, mutect2, varscan2
- KLHL14 | c.702G>A p.S234= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs369667242; called by muse, mutect2, varscan2
- TBX18 | c.1089T>A p.I363= | Silent (SNP) | VAF 73/210 reads (35%) | catalogued as COSV63736707; called by muse, mutect2, varscan2
- TTYH3 | c.1191C>G p.V397= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV51859947; called by muse, mutect2, varscan2
